Somatic mutation profile of tumor specimen MMRF_2473_1_BM_CD138pos (aliquot MMRF_2473_1_BM_CD138pos_T1_KHS5U_L11620) from MMRF case MMRF_2473, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.3 years (27,139 days).
Specimen MMRF_2473_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8f2d1ab-ae8b-4fb6-b3ed-9c5237e7692a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2473_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2473_1_PB_Whole_C3_KHS5U_L11621; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/036b8a0b-a322-45fd-88f6-b2aa8b578dbf

The open-access MAF lists 113 somatic variants for this specimen: 44 protein-altering or splice-affecting, 19 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 29, Silent 19, Intron 12, Splice Region 3, 3'Flank 3, 5'UTR 3, 5'Flank 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs757936962, COSV58647978; called by muse, mutect2, varscan2
- ASIC5 | c.41-2A>C p.X14_splice | Splice Site (SNP) | VAF 42/81 reads (52%) | catalogued as rs201085326; called by muse, mutect2, varscan2
- D2HGDH | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs764487647, COSV100344058; called by muse, mutect2, varscan2
- DIS3 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706787; called by muse, mutect2, varscan2
- ESPNL | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.828); catalogued as rs144639872; called by muse, mutect2, varscan2
- GULP1 | c.843+7A>G | Splice Region (SNP) | VAF 63/110 reads (57%) | catalogued as rs774570245; called by muse, mutect2, varscan2
- HMSD | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 9/286 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV68817033; called by muse, mutect2
- HNRNPA1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as rs61910737, COSV52937419, COSV52938449; called by muse, mutect2
- IGLV3-1 | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs774205851; called by muse, varscan2
- IGLV3-1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as rs371113616; called by muse, varscan2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, varscan2
- ITGA10 | c.1092C>A p.N364K | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV65197464; called by muse, mutect2, varscan2
- OR13C2 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 22/568 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV73377649; called by muse, mutect2
- RP1 | c.4941dup p.P1648Sfs*13 | Frame Shift Ins (INS) | VAF 77/158 reads (49%) | catalogued as rs765725238; called by mutect2, varscan2
- SCARA3 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1223345024; called by muse, mutect2, varscan2
- SPPL3 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV62233243; called by muse, mutect2
- SRGAP2 | c.2714G>A p.R905H (on ENST00000624873 / NM_001170637.4; = p.R906H on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/308 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs568887983, COSV55336271; called by muse, mutect2, varscan2
- UMODL1 | c.2557G>A p.G853S (on ENST00000408910 / NM_001004416.2; = p.G981S on NM_173568.3) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs774606311; called by muse, mutect2, varscan2
- ZNF33A | c.1109A>G p.N370S (on ENST00000458705 / NM_006974.3; = p.N371S on NM_006954.2) | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.318); catalogued as rs200969207; called by muse, mutect2, varscan2
- ANO3 | c.78A>T p.K26N | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2
- AURKB | c.574C>G p.H192D | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C16orf46 | c.463T>C p.Y155H | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C3orf20 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CERK | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CNTNAP2 | c.3646G>T p.A1216S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DOCK5 | c.5093+2T>C p.X1698_splice | Splice Site (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- EPB41L2 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 75/177 reads (42%) | called by muse, mutect2, varscan2
- FGD4 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- HOXC10 | c.1006A>C p.T336P | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MAP7D2 | c.748G>C p.A250P | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MKKS | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 108/212 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MYH8 | c.5266G>A p.E1756K | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- RPN1 | c.261G>A p.Q87= | Splice Region (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- RPN1 | c.260A>C p.Q87P | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- SIDT2 | c.2322+5G>T | Splice Region (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- SLC12A2 | c.2545A>C p.N849H | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC9C2 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 118/576 reads (20%) | called by muse, mutect2, varscan2
- SUDS3 | c.823A>C p.I275L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- SYT17 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZBTB42 | c.909del p.S305Afs*45 | Frame Shift Del (DEL) | VAF 49/128 reads (38%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.3446A>T p.E1149V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF214 | c.407T>A p.F136Y | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- ZNF569 | c.200G>C p.W67S | Missense Mutation (SNP) | VAF 114/223 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZNF772 | c.869G>C p.G290A | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- AL772284.1 | c.741C>T p.A247= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1047115364; called by muse, mutect2, varscan2
- ATG9A | c.618G>C p.L206= | Silent (SNP) | VAF 48/97 reads (49%) | called by muse, mutect2, varscan2
- ATP1A4 | c.1026G>A p.E342= | Silent (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- CHIC1 | c.273G>A p.V91= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as rs745922037; called by muse, mutect2, varscan2
- CRYBB3 | c.199C>T p.L67= | Silent (SNP) | VAF 7/141 reads (5%) | catalogued as rs1345836236; called by muse, mutect2
- DCAF12L1 | c.657G>T p.L219= | Silent (SNP) | VAF 52/270 reads (19%) | called by muse, mutect2, varscan2
- DPP7 | c.588C>T p.G196= | Silent (SNP) | VAF 58/187 reads (31%) | catalogued as rs965714858; called by muse, mutect2, varscan2
- EPB41L3 | c.2172T>A p.T724= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- OR2J3 | c.126G>A p.L42= | Silent (SNP) | VAF 20/355 reads (6%) | catalogued as COSV65849626; called by muse, mutect2
- PDE2A | c.447G>A p.P149= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs956348156, COSV57811741; called by muse, mutect2, varscan2
- PEBP4 | c.171C>T p.G57= | Silent (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.3486C>T p.V1162= (on ENST00000394691; = p.V1218= on NM_001308147.2) | Silent (SNP) | VAF 77/175 reads (44%) | catalogued as rs752022533; called by muse, mutect2, varscan2
- RTN4 | c.171G>A p.R57= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs777343082; called by muse, mutect2, varscan2
- SERPINA2 | c.516C>T p.I172= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as rs1218380337; called by muse, mutect2
- SLITRK2 | c.33A>G p.L11= | Silent (SNP) | VAF 40/120 reads (33%) | called by muse, mutect2, varscan2
- SPIRE1 | c.2163G>A p.V721= (on ENST00000409402 / NM_001128626.2; = p.V707= on NM_020148.3) | Silent (SNP) | VAF 88/183 reads (48%) | called by muse, mutect2, varscan2
- TEK | c.858G>C p.G286= | Silent (SNP) | VAF 11/121 reads (9%) | catalogued as COSV66230685; called by muse, mutect2
- WAS | c.597A>T p.T199= | Silent (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- WDR97 | c.1182G>A p.P394= | Silent (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- ACTRT1 | c.-161G>A | 5'UTR (SNP) | VAF 75/119 reads (63%) | called by muse, mutect2, varscan2
- ADRA2A | c.-556G>C | 5'UTR (SNP) | VAF 98/187 reads (52%) | catalogued as rs1183157218; called by muse, mutect2, varscan2
- AEBP2 | c.*279G>A | 3'UTR (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- ANKS3 | c.492-133T>G | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- AP002495.1 | c.436+126A>T | Intron (SNP) | VAF 255/564 reads (45%) | catalogued as rs1266503457; called by muse, mutect2, varscan2
- ARHGEF17 | c.3270+186G>A | Intron (SNP) | VAF 65/146 reads (45%) | catalogued as rs914578528; called by muse, mutect2, varscan2
- BBS5 | c.682-46T>C | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021192 A>G | 5'Flank (SNP) | VAF 67/160 reads (42%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021704 G>C | 5'Flank (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- C10orf53 | c.*717T>C | 3'UTR (SNP) | VAF 52/187 reads (28%) | catalogued as rs1486788766; called by muse, mutect2, varscan2
- C2orf49 | c.*2334A>T | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- CAPRIN1 | c.2065+394A>G | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- CARD8 | c.*69T>C | 3'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- CCDC80 | c.*519C>A | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- CCNJL | c.424+6779G>A | Intron (SNP) | VAF 76/145 reads (52%) | catalogued as rs573145650; called by muse, mutect2, varscan2
- CHRM3 | c.*1456G>A | 3'UTR (SNP) | VAF 119/155 reads (77%) | catalogued as rs1411026195; called by muse, mutect2, varscan2
- COL14A1 | c.5312-469C>A | Intron (SNP) | VAF 24/384 reads (6%) | called by muse, mutect2
- DIAPH2 | c.*1665G>C | 3'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- DMD | c.*1316C>T | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- FAM204A | c.*82G>A | 3'UTR (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- FGF11 | c.608-140T>G | Intron (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- FYB1 | c.1394+80A>C | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, varscan2
- HOXA4 | c.*193C>T | 3'UTR (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- KCNH8 | c.*1225T>C | 3'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- KCNQ4 | c.*1581G>T | 3'UTR (SNP) | VAF 92/179 reads (51%) | called by muse, mutect2, varscan2
- KCNS1 | c.*1796C>T | 3'UTR (SNP) | VAF 17/38 reads (45%) | catalogued as rs530036118; called by muse, mutect2, varscan2
- LAMB1 | c.4188+23T>A | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- MAGEA11 | c.*97C>A | 3'UTR (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100290712; called by muse, mutect2
- MOBP | chr3:39514375 C>T | 3'Flank (SNP) | VAF 82/189 reads (43%) | called by muse, mutect2, varscan2
- MS4A1 | c.*403dup | 3'UTR (INS) | VAF 30/62 reads (48%) | called by mutect2, varscan2
- MYOCD | chr17:12764708 C>T | 3'Flank (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- NCAM2 | c.*2053G>A | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- PCDH17 | c.*250A>C | 3'UTR (SNP) | VAF 11/12 reads (92%) | called by muse, mutect2, varscan2
- PDXK | c.*3918A>C | 3'UTR (SNP) | VAF 77/139 reads (55%) | called by muse, mutect2, varscan2
- POLR2E | chr19:1095363 A>G | 5'Flank (SNP) | VAF 37/83 reads (45%) | catalogued as rs1309169950; called by muse, mutect2, varscan2
- PTGER3 | c.1077+1419G>A | Intron (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- RDH16 | c.*312T>A | 3'UTR (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2, varscan2
- RGP1 | c.*46del | 3'UTR (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- RHOBTB1 | c.*645T>G | 3'UTR (SNP) | VAF 39/146 reads (27%) | called by muse, mutect2, varscan2
- SOCS2 | c.140-42G>A | Intron (SNP) | VAF 36/129 reads (28%) | called by muse, mutect2, varscan2
- TFAP2A | chr6:10396868 G>A | 3'Flank (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- THBS1 | c.*1451A>G | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- TMEM242 | c.*1027A>G | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- TRIQK | c.*519T>C | 3'UTR (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- UNC93A | c.-126C>T | 5'UTR (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- USP48 | c.*509A>C | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- WRNIP1 | c.*945T>C | 3'UTR (SNP) | VAF 44/108 reads (41%) | catalogued as rs1303121710; called by muse, mutect2, varscan2
- YTHDF1 | c.*146G>A | 3'UTR (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- ZBTB44 | c.*3208G>A | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- ZNF541 | c.*414C>G | 3'UTR (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
